MMRF case MMRF_1950 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/635644ae-9179-42bc-a908-25ea0f5d0e8e

Demographics
Sex at birth: male; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.8 years (27,690 days); ISS stage: III; Days to last known disease status: 1,027 days (2.8 years); Days to last follow up: 1,027 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 289 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days; Days to treatment end: 289 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,027.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 5.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 72.4 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 9.96 µg/mL; Hemoglobin 4.4 mmol/L; Leukocytes 6.68 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 3.1 mmol/L; Albumin 34 g/L; Total Protein 11.7 g/dL; Glucose 6.99 mmol/L.
- Day 93 (ECOG 1): M Protein 0.1 g/dL; Immunoglobulin G 5.07 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.76 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Total Protein 6.1 g/dL; Glucose 7.15 mmol/L.
- Day 198 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 8.36 g/L; Hemoglobin 8 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 7.43 mmol/L.
- Day 289 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.81 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 9.53 ×10⁹/L; Absolute Neutrophil 7.31 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.23 mmol/L; Total Protein 6.6 g/dL; Glucose 7.48 mmol/L.
- Day 373: M Protein 0 g/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 1.01 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 9.34 ×10⁹/L; Absolute Neutrophil 5.35 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Total Protein 7.6 g/dL; Glucose 6.44 mmol/L.
- Day 463 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 3.88 g/L; Immunoglobulin M 1.01 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.54 ×10⁹/L; Absolute Neutrophil 4.38 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Total Protein 7.9 g/dL; Glucose 5.45 mmol/L.
- Day 554 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 17.9 g/L; Immunoglobulin A 3.75 g/L; Immunoglobulin M 1.14 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5.14 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL; Glucose 6.33 mmol/L.
- Day 674: Immunoglobulin G 18.1 g/L; Immunoglobulin A 4.31 g/L; Immunoglobulin M 1.11 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 5.01 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 5.78 mmol/L.
- Day 723: Hemoglobin 8.31 mmol/L; Leukocytes 5.26 ×10⁹/L; Absolute Neutrophil 4.01 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 7.65 mmol/L.
- Day 816: Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 3.05 g/L; Immunoglobulin M 1.21 g/L; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 4.89 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 950: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 1.31 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.91 ×10⁹/L; Absolute Neutrophil 2.74 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.33 mmol/L.
- Day 1,012: Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 3.01 g/L; Immunoglobulin M 1.3 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 4.65 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 43.4 g/L; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -6: Weight: 83 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_1950_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1950_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
